Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19W, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19W-06A (Metastatic).

1CD-0-3

Melanoma, NOS 8720/3

12/15/10

W

PATIENT HISTORY:

Not given

PRE-OP DIAGNOSIS: Right axillary mass

POST-OP DIAGNOSIS: Same

PROCEDURE: Excision of melanoma right axilla

Site code: Axilla, subcutaneous tissue C49.3

**FINAL DIAGNOSIS:**

SOFT TISSUE, AXILLARY MASS, RIGHT, EXCISION -

- A. METASTATIC MALIGNANT MELANOMA IN SUBCUTANEOUS FATTY TISSUE, IN LARGE PART NECROTIC (TWO NODULES, 2.8 AND 3.5 CM).
- B. SCAR OF SKIN, WITH CHRONIC INFLAMMATION, MILD, NEGATIVE FOR MELANOCYTIC LESION.
- C. EXTENSION OF NEOPLASM TO DEEP MARGIN OF RESECTION, FOCAL, WITH THERMAL ARTIFACT; OTHER MARGINS FREE OF NEOPLASM.

COMMENT:

Please see previous reports, [REDACTED] and [REDACTED]. The special immunoperoxidase stain, S100 is positive and confirms the above diagnosis.

Source: NCI Genomic Data Commons file c2e40787-0a8a-4a19-b505-61e556913381 (TCGA-ER-A19W.A2959CAA-E51A-48EB-9FCD-60E5E5A0B43D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).